Surgical pathology report (de-identified scan), TCGA case TCGA-MI-A75I, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MI-A75I-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY ----

ICD 0-3
Carcinoma, hepatocellular NOS
Site Liver C22.0
817013

W 8/13/13

MEDICAL RECORD	SURGICAL PATHOLOGY
PATHOLOGY REPORT	
Laboratory:	Accession No.
Submitted by:	Date obtained:
Specimen (Received LEFT LATERAL RESECTOMY LIVER	
BRIEF CLINICAL HISTORY:	
PREOPERATIVE DIAGNOSIS: Hepatocellular carcinoma	
OPERATIVE FINDINGS:	
POSTOPERATIVE DIAGNOSIS: Hepatocellular carcinoma	
Surgeon/physician:	
PATHOLOGY REPORT	
Laboratory:	Accession No.

GROSS DESCRIPTION:

The specimen consists of a 153 gram, 15.2 x 7.1 x 3.5 cm, segment of liver displaying a tan-red, granular resection margin with multiple staples and clips. The resection margin is inked black. The overlying capsule is tan-pink to purple, and granular with abundant nodularity. The capsular aspect is inked blue. The specimen is serially sectioned to reveal a 5.3 x 5.2 x 4.8 cm, tan-yellow to white, granular, nodular mass that is 1.3 cm from the liver resection margin. The mass is multifocal ranging from 0.2 to 5.8 cm in greatest dimensions. The smaller nodules extend to within 0.3 cm of the hepatic resection margin. The masses grossly extend to the overlying capsule. The uninvolved liver parenchyma is tan-yellow to brown and unremarkable.

Representative sections are submitted as follows: 1-4- largest mass to resection margin; 5- smallest nodule to closest resection margin; 6-9- nodules to overlying capsule; 10- largest mass with adjacent uninvolved liver parenchyma. Please note a representative portion is taken for tissue bank.

MICROSCOPIC EXAM

DIAGNOSIS:

Left lateral liver, resection:

SPECIMEN: Liver
PROCEDURE: Partial hepatectomy
TUMOR SIZE: 5.3 x 5.2 x 4.8 cm
TUMOR FOCALITY: Multiple
HISTOLOGIC TYPE: Hepatocellular carcinoma
HISTOLOGIC GRADE: G1 (well-differentiated)
TUMOR EXTENSION: Tumor confined to liver
MARGINS:
Parenchymal margin
- uninvolved by invasive carcinoma (distance of invasive carcinoma from closest margin: 5 mm)
LYMPH-VASCULAR INVASION: Indeterminate
PERINEURAL INVASION: Not identified
PATHOLOGIC STAGING:

[page 2 of 2]
Primary Tumor: pT2
Regional Lymph Nodes: pNx
Distant Metastasis: Not applicable

COMMENT: concurs with the diagnosis of malignancy. Physician
was notified via

Source: NCI Genomic Data Commons file db67bb7f-3262-4f49-96f2-2ff96a4461da (TCGA-MI-A75I.4630A897-45DC-4122-BB86-A2943FE27CEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).